Somatic mutation profile of tumor specimen TARGET-40-NAAHBY-02A (aliquot TARGET-40-NAAHBY-02A-01D) from TARGET case TARGET-40-NAAHBY, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 15.2 years (5,538 days).
Specimen TARGET-40-NAAHBY-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f32bfcad-7a35-454e-8bc7-f64f708b3d82.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHBY-10A (Blood Derived Normal), aliquot TARGET-40-NAAHBY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65046a71-1eb9-4b9f-bfd2-613e43fd4e8a

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.405C>G p.C135W | Missense Mutation (SNP) | VAF 32/73 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519976, COSV52665429, COSV52669330, COSV52682693, COSV52815283; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PHTF2 | c.2255C>T p.P752L (on ENST00000248550 / NM_001366089.1; = p.P714L on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759471348, COSV50325161, COSV50325343; called by muse, mutect2, varscan2
- PLXNA3 | c.5203G>A p.V1735M | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63754434, COSV63755672; called by muse, mutect2, varscan2
- ARMCX2 | c.470T>A p.M157K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSMD2 | c.6455G>T p.G2152V | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ENTHD1 | c.686A>C p.K229T | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- PTPRD | c.4669G>A p.V1557I | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SCAF4 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SCN4A | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- STYXL2 | c.1447A>G p.R483G | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TBX22 | c.11G>C p.S4T | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- BCOR | c.1276C>T p.L426= | Silent (SNP) | VAF 28/172 reads (16%) | catalogued as rs760754322; called by muse, mutect2, varscan2
- DQX1 | c.1542C>G p.A514= | Silent (SNP) | VAF 55/196 reads (28%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.103C>T p.L35= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs1357186159; called by muse, mutect2
- SIL1 | c.207G>T p.V69= | Silent (SNP) | VAF 53/226 reads (23%) | called by muse, mutect2, varscan2
